Somatic mutation profile of tumor specimen MBCProject_0251_T1_WES (aliquot MBCProject_0251_T1_WES_1) from CMI case MBCProject_0251, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 50.6 years (18,473 days).
Specimen MBCProject_0251_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b7f80b9-0c08-427b-809e-db5ab9011ed0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0251_SALIVA (Saliva), aliquot MBCProject_0251_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40b1654c-2554-4aef-bf84-656e7ad7e7b3

The open-access MAF lists 223 somatic variants for this specimen: 137 protein-altering or splice-affecting, 56 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 56, Intron 13, Nonsense Mutation 7, 3'UTR 6, 5'UTR 5, Splice Region 3, Splice Site 3, RNA 3, Frame Shift Del 3, 3'Flank 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 126/350 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057519827, COSV52782264; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 49/101 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.2759T>C p.V920A | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs1405959961; called by muse, mutect2
- ARHGAP33 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.983); catalogued as rs374221923; called by muse, mutect2, varscan2
- C10orf71 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV60506677; called by muse, mutect2, varscan2
- C4orf19 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1388470766, COSV99448725; called by muse, mutect2
- CCDC153 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as rs371721620; called by muse, mutect2, varscan2
- COL4A2 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV64627296; called by muse, mutect2, varscan2
- COLQ | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 119/236 reads (50%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.952); catalogued as rs888456085; called by muse, mutect2, varscan2
- CPLX3 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV59002363, COSV59003859; called by muse, mutect2, varscan2
- DAAM2 | c.2387G>C p.R796T | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs770093066, COSV51302675; called by muse, mutect2, varscan2
- DIDO1 | c.6376G>C p.E2126Q | Missense Mutation (SNP) | VAF 84/451 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV56623901; called by muse, mutect2, varscan2
- DNAH3 | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV54534230; called by muse, mutect2
- DYRK4 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99155324; called by muse, mutect2
- ENDOV | c.545C>G p.S182* | Nonsense Mutation (SNP) | VAF 23/186 reads (12%) | catalogued as rs374533284; called by muse, mutect2, varscan2
- ERC1 | c.2316G>C p.K772N (on ENST00000360905 / NM_178040.4; = p.K744N on NM_178039.4) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61698621; called by muse, mutect2, varscan2
- FBXL22 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1187127356; called by muse, mutect2, varscan2
- GRK7 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 136/293 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374257219, COSV53823386, COSV99380043; called by muse, mutect2, varscan2
- HMGCS2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs771524777; called by muse, mutect2
- JPH2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV65905807; called by muse, mutect2, varscan2
- KANK2 | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV62007551; called by muse, mutect2, varscan2
- KIAA0100 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV66495318, COSV66495454; called by muse, mutect2, varscan2
- MAG | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs372192843; called by muse, mutect2, varscan2
- MAP1B | c.3731C>T p.S1244L | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57098730; called by muse, mutect2, varscan2
- MBD5 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV68699275; called by muse, mutect2, varscan2
- MMP17 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as rs780582086; called by muse, mutect2, varscan2
- MYH6 | c.5653G>A p.E1885K | Missense Mutation (SNP) | VAF 57/518 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs760353963, CM1513239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2T1 | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 10/195 reads (5%) | catalogued as COSV63541613; called by muse, mutect2
- PCDH15 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV100224442, COSV57314634; called by muse, mutect2, varscan2
- PHACTR4 | c.911C>G p.S304* (on ENST00000373839 / NM_001350159.2; = p.S314* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | catalogued as COSV65783823; called by muse, varscan2
- PHC2 | c.1720G>A p.E574K (on ENST00000257118 / NM_198040.2; = p.E39K on NM_004427.4) | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs980106149, COSV57104950; called by muse, mutect2, varscan2
- PIGO | c.2224G>A p.V742M | Missense Mutation (SNP) | VAF 29/576 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1232633765; called by muse, mutect2
- PLVAP | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs148432183, COSV53086417; called by muse, mutect2, varscan2
- POLR3C | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs782596552; called by muse, mutect2, varscan2
- QRICH2 | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs754539662; called by muse, mutect2, varscan2
- RMC1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99339885; called by muse, mutect2
- SCNN1G | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs372056840; called by muse, mutect2, varscan2
- SEC16A | c.4741G>A p.D1581N | Missense Mutation (SNP) | VAF 87/552 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99260227; called by muse, mutect2, varscan2
- SLC4A9 | c.1685C>T p.S562F (on ENST00000507527 / NM_001258428.2; = p.S538F on NM_031467.3) | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV50186353, COSV50198441; called by muse, mutect2, varscan2
- TCN2 | c.1222+3G>A | Splice Region (SNP) | VAF 34/148 reads (23%) | catalogued as rs1158438419; called by muse, mutect2, varscan2
- TMEM177 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs749752145; called by muse, mutect2, varscan2
- TRAF3IP3 | c.915+8G>A | Splice Region (SNP) | VAF 32/396 reads (8%) | catalogued as rs748137793; called by muse, mutect2
- TRIOBP | c.4810G>A p.D1604N | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100731115; called by muse, mutect2
- TRPM5 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.313); catalogued as rs556609638; called by muse, mutect2, varscan2
- TTN | c.91039G>A p.V30347M (on ENST00000591111; = p.V22923M on NM_003319.4) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | PolyPhen possibly damaging (0.695); catalogued as rs756469423, COSV59877746; ClinVar: uncertain significance; called by mutect2, varscan2
- TUBE1 | c.954-1G>A p.X318_splice | Splice Site (SNP) | VAF 8/102 reads (8%) | catalogued as COSV57889123; called by muse, mutect2
- UTS2R | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs767518669; called by muse, mutect2, varscan2
- ZNF135 | c.799G>A p.E267K (on ENST00000313434 / NM_001289401.2; = p.E279K on NM_003436.4) | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1436141791; called by muse, mutect2
- ZNF425 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs189687536; called by muse, mutect2, varscan2
- ZNF507 | c.2410C>T p.H804Y | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61331763; called by muse, mutect2, varscan2
- ZNF608 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60438535; called by muse, mutect2, varscan2
- ABCB4 | c.1340A>G p.D447G | Missense Mutation (SNP) | VAF 133/477 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABHD16A | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ACOT4 | c.282del p.K95Sfs*94 | Frame Shift Del (DEL) | VAF 45/396 reads (11%) | called by mutect2, pindel, varscan2
- AK9 | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- AMER1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ANKRD30A | c.3668T>C p.F1223S (on ENST00000611781; = p.F1167S on NM_052997.2) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ATP12A | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- CACNA2D1 | c.2111G>C p.R704T (on ENST00000356253 / NM_001366867.1; = p.R692T on NM_000722.4) | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CALD1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 46/390 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.026); called by muse, varscan2
- CAPS2 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- CCDC149 | c.1245G>C p.L415F (on ENST00000635206 / NM_001330643.2; = p.L404F on NM_173463.5) | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CHI3L2 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CMYA5 | c.11303G>A p.C3768Y | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4A | c.3316G>C p.D1106H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- EDEM3 | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- EIF2AK3 | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2
- EPB41L1 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 20/147 reads (14%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ESR1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- EVC | c.2097+5G>C | Splice Region (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
- FLT1 | c.3351G>T p.M1117I | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRY | c.3761A>T p.D1254V | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FSIP2 | c.7320A>C p.K2440N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GIPR | c.192del p.F65Sfs*90 | Frame Shift Del (DEL) | VAF 69/484 reads (14%) | called by mutect2, pindel, varscan2
- GNB1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRB7 | c.464-1G>A p.X155_splice | Splice Site (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- GTPBP8 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2
- HABP4 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.342); called by muse, mutect2
- HMG20B | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HTT | c.5358C>G p.I1786M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- IMMT | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2
- IRAK3 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1109 | c.8553dup p.P2852Sfs*19 | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- KLK2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- LCE2D | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); called by muse, mutect2
- LRRC4 | c.1641C>G p.F547L | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MAP3K4 | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- MBD3 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 84/225 reads (37%) | called by muse, mutect2, varscan2
- MR1 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 34/463 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- MSL2 | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- MYH10 | c.5256G>C p.M1752I | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYT1L | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDC80 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- NRDC | c.3334G>C p.V1112L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUAK2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- NUP133 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OLFM4 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- PABPC4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE1A | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, varscan2
- PGRMC2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- PLSCR4 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, varscan2
- POLQ | c.7108G>A p.E2370K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRKCH | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 64/208 reads (31%) | called by muse, mutect2, varscan2
- PRKDC | c.9172G>T p.D3058Y | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PROS1 | c.1881C>G p.F627L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- PRPF40B | c.2291C>T p.S764F (on ENST00000380281; = p.S751F on NM_012272.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- PRPS1L1 | c.690C>G p.C230W | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PSD4 | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTPN12 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); called by muse, mutect2
- QSER1 | c.3393G>A p.M1131I (on ENST00000399302; = p.M1260I on NM_001076786.3) | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.041); called by muse, mutect2
- RALGAPA1 | c.106+1G>A p.X36_splice | Splice Site (SNP) | VAF 40/343 reads (12%) | called by muse, mutect2, varscan2
- RBM10 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- RGS2 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 56/666 reads (8%) | called by muse, mutect2
- RP1L1 | c.3823G>A p.E1275K | Missense Mutation (SNP) | VAF 120/474 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RYR2 | c.6290G>C p.G2097A | Missense Mutation (SNP) | VAF 41/494 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.633); called by muse, mutect2
- SDCCAG8 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 178/426 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SHANK3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SHCBP1 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- SLC22A3 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC6A18 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMCR8 | c.2655G>A p.M885I | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- STON1-GTF2A1L | c.2641C>A p.P881T | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- STRN | c.2064C>G p.I688M | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SUGP2 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SYNE2 | c.13091C>T p.S4364F | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- TACC2 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TEP1 | c.6671_6681del p.H2224Rfs*31 | Frame Shift Del (DEL) | VAF 49/212 reads (23%) | called by mutect2, pindel, varscan2
- TMEM101 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2
- TMEM151B | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- TMEM74 | c.728dup p.V244Rfs*45 | Frame Shift Ins (INS) | VAF 21/159 reads (13%) | called by mutect2, pindel, varscan2
- TRIM66 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC21A | c.1950C>G p.I650M | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.284); called by muse, mutect2
- TTN | c.27953G>C p.R9318T (on ENST00000591111; = p.R8391T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/270 reads (8%) | PolyPhen benign (0.001); called by muse, mutect2
- ZBTB7B | c.193G>A p.E65K (on ENST00000292176; = p.E99K on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ZEB2 | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF470 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ABTB2 | c.996C>T p.L332= | Silent (SNP) | VAF 37/260 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.2313G>A p.L771= (on ENST00000428638 / NM_001282290.1; = p.L430= on NM_199282.3) | Silent (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- ATM | c.2505A>G p.V835= | Silent (SNP) | VAF 95/190 reads (50%) | catalogued as rs1057523506; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP12A | c.1146C>T p.L382= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as rs778320466, COSV54514126; called by muse, mutect2, varscan2
- CAMKK1 | c.789C>T p.L263= | Silent (SNP) | VAF 136/325 reads (42%) | catalogued as rs754737840, COSV50114718; called by muse, mutect2, varscan2
- CASK | c.2628G>A p.Q876= (on ENST00000378163 / NM_001367721.1; = p.Q871= on NM_003688.3) | Silent (SNP) | VAF 35/209 reads (17%) | called by muse, mutect2, varscan2
- CCDC96 | c.414C>T p.V138= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV59508297; called by muse, varscan2
- CNGB1 | c.1920G>A p.K640= | Silent (SNP) | VAF 54/253 reads (21%) | called by muse, mutect2, varscan2
- COL22A1 | c.123C>T p.F41= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV57348450; called by muse, varscan2
- CTSW | c.648G>A p.P216= | Silent (SNP) | VAF 102/438 reads (23%) | catalogued as rs143198836; called by muse, mutect2, varscan2
- DUSP29 | c.255G>A p.L85= | Silent (SNP) | VAF 72/402 reads (18%) | called by muse, mutect2, varscan2
- ELOA2 | c.2142G>A p.L714= | Silent (SNP) | VAF 27/476 reads (6%) | catalogued as COSV55296047; called by muse, mutect2
- FAM47A | c.1287G>T p.L429= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs1259476313; called by muse, mutect2, varscan2
- FAM71A | c.954C>T p.I318= | Silent (SNP) | VAF 40/507 reads (8%) | catalogued as rs763960027, COSV54235687; called by muse, mutect2
- FAM83E | c.1219C>T p.L407= | Silent (SNP) | VAF 33/237 reads (14%) | catalogued as rs1394475252; called by muse, mutect2, varscan2
- FEZ1 | c.645C>T p.F215= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs372200287; called by mutect2, varscan2
- FPGT-TNNI3K | c.609G>A p.L203= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs897169757; called by muse, mutect2, varscan2
- GLIS2 | c.1245G>A p.P415= | Silent (SNP) | VAF 83/741 reads (11%) | catalogued as rs755435780; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRPR | c.579C>T p.F193= | Silent (SNP) | VAF 42/225 reads (19%) | called by muse, mutect2, varscan2
- HOXD4 | c.552G>A p.R184= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as rs1416403766, COSV60459935; called by muse, mutect2
- IGFALS | c.906C>T p.I302= | Silent (SNP) | VAF 102/629 reads (16%) | catalogued as rs201808241; called by muse, mutect2, varscan2
- IL12B | c.582G>A p.Q194= | Silent (SNP) | VAF 86/572 reads (15%) | catalogued as rs1562112336; called by muse, mutect2, varscan2
- JPH2 | c.1803C>T p.T601= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as rs1060503799, COSV65906226; ClinVar: likely benign; called by muse, mutect2
- JUNB | c.879C>T p.I293= | Silent (SNP) | VAF 85/459 reads (19%) | catalogued as rs889966481, COSV56878245, COSV56878450; called by muse, mutect2, varscan2
- KCNH5 | c.396G>A p.T132= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs143574473; called by muse, mutect2, varscan2
- KCTD8 | c.312C>T p.F104= | Silent (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
- LAMA4 | c.3978G>A p.L1326= (on ENST00000230538 / NM_001105206.3; = p.L1319= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/183 reads (6%) | catalogued as COSV100038165; called by muse, mutect2
- LRAT | c.318C>A p.A106= | Silent (SNP) | VAF 70/336 reads (21%) | called by muse, mutect2, varscan2
- LRRC4B | c.1002G>A p.T334= | Silent (SNP) | VAF 65/339 reads (19%) | called by muse, mutect2, varscan2
- LRRC8E | c.1980C>A p.L660= | Silent (SNP) | VAF 18/310 reads (6%) | catalogued as COSV100142954, COSV60719158; called by muse, mutect2
- MAF1 | c.471G>A p.E157= | Silent (SNP) | VAF 74/289 reads (26%) | called by muse, mutect2, varscan2
- MAN2B2 | c.198C>T p.R66= | Silent (SNP) | VAF 63/376 reads (17%) | catalogued as rs779997292, COSV53454200; called by muse, mutect2, varscan2
- MBOAT7 | c.267C>T p.L89= | Silent (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- MFHAS1 | c.2085G>C p.L695= | Silent (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- MIDEAS | c.663C>T p.F221= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs749437985, COSV54094389; called by muse, varscan2
- MYO5A | c.2043G>C p.L681= | Silent (SNP) | VAF 68/392 reads (17%) | catalogued as COSV62560092; called by muse, mutect2, varscan2
- NDUFA8 | c.39G>A p.L13= | Silent (SNP) | VAF 98/614 reads (16%) | called by muse, mutect2, varscan2
- NOL12 | c.48G>A p.P16= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs757228384, COSV100767157; called by muse, mutect2, varscan2
- NYX | c.672C>T p.G224= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- OR14A16 | c.111G>A p.L37= | Silent (SNP) | VAF 24/296 reads (8%) | catalogued as COSV62926524; called by muse, mutect2
- PCDHB1 | c.504G>A p.Q168= | Silent (SNP) | VAF 18/335 reads (5%) | called by muse, mutect2
- PDE4D | c.408G>A p.L136= | Silent (SNP) | VAF 34/662 reads (5%) | called by muse, mutect2
- PRR5L | c.15C>T p.F5= | Silent (SNP) | VAF 13/247 reads (5%) | catalogued as rs1041921488; called by muse, mutect2
- RANBP17 | c.1648C>T p.L550= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV66653221; called by muse, mutect2, varscan2
- SBNO1 | c.1686C>G p.V562= (on ENST00000420886; = p.V561= on NM_018183.5) | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2
- SERPINA4 | c.288C>T p.H96= | Silent (SNP) | VAF 48/546 reads (9%) | catalogued as rs1166650157; called by muse, mutect2
- SLC10A7 | c.366G>A p.V122= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as COSV53887304; called by muse, mutect2, varscan2
- SLC35F4 | c.309C>T p.T103= (on ENST00000339762 / NM_001352015.2; = p.T67= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/279 reads (12%) | catalogued as rs749549339; called by muse, mutect2, varscan2
- SPHK2 | c.1098C>T p.L366= | Silent (SNP) | VAF 71/173 reads (41%) | catalogued as rs551364710, COSV55335357; called by muse, mutect2, varscan2
- SPIDR | c.2667C>T p.S889= | Silent (SNP) | VAF 48/250 reads (19%) | catalogued as rs751128787; called by muse, mutect2, varscan2
- SRRM4 | c.1671G>A p.R557= | Silent (SNP) | VAF 245/633 reads (39%) | called by muse, mutect2, varscan2
- TADA2B | c.621C>T p.D207= | Silent (SNP) | VAF 49/230 reads (21%) | called by muse, mutect2, varscan2
- TIMM23B | c.351G>A p.L117= | Silent (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- VWA1 | c.909C>T p.P303= | Silent (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- WDR91 | c.540G>A p.A180= | Silent (SNP) | VAF 26/188 reads (14%) | catalogued as rs377257563; called by muse, mutect2, varscan2
- YY1AP1 | c.1155G>A p.Q385= (on ENST00000295566 / NM_139118.2; = p.Q328= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/678 reads (6%) | catalogued as COSV55120627; called by muse, mutect2
- ABHD16A | c.1308-14C>G | Intron (SNP) | VAF 13/53 reads (25%) | catalogued as rs772025083; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3213G>C | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- C11orf40 | n.31G>C | RNA (SNP) | VAF 67/273 reads (25%) | called by muse, mutect2, varscan2
- CRACR2B | c.694-41G>A | Intron (SNP) | VAF 28/370 reads (8%) | catalogued as rs747145870; called by muse, mutect2
- CRTC2 | c.703-17C>T | Intron (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- CYP19A1 | c.*212G>A | 3'UTR (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- DAP | c.*215G>A | 3'UTR (SNP) | VAF 52/391 reads (13%) | called by muse, mutect2, varscan2
- EMC3-AS1 | chr3:10007569 G>A | 3'Flank (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- FAM126A | c.-155C>G | 5'UTR (SNP) | VAF 216/661 reads (33%) | called by muse, mutect2, varscan2
- IGFALS | c.*29C>T | 3'UTR (SNP) | VAF 27/179 reads (15%) | called by muse, mutect2, varscan2
- INS | c.*31G>T | 3'UTR (SNP) | VAF 77/622 reads (12%) | catalogued as rs779345894, COSV99171117; called by muse, mutect2, varscan2
- IRF9 | c.496-53G>A | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, varscan2
- LUC7L | c.61+350C>T | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2
- MMP16 | c.1222+5155A>G | Intron (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- NDUFA10 | c.1000-12323C>T | Intron (SNP) | VAF 70/221 reads (32%) | catalogued as rs561803332; called by muse, mutect2, varscan2
- OTOA | c.1731-23G>A | Intron (SNP) | VAF 70/588 reads (12%) | catalogued as rs200631288; called by muse, mutect2, varscan2
- PKD1L2 | n.926G>A | RNA (SNP) | VAF 18/28 reads (64%) | catalogued as rs1207086283; called by muse, mutect2, varscan2
- RHOJ | c.*114G>A | 3'UTR (SNP) | VAF 61/184 reads (33%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+14014C>G | Intron (SNP) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- SLC25A25 | c.-8C>G | 5'UTR (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2, varscan2
- SPTA1 | c.*13C>T | 3'UTR (SNP) | VAF 18/532 reads (3%) | catalogued as COSV63526074; called by muse, mutect2
- TCP11 | chr6:35141289 G>A | 5'Flank (SNP) | VAF 22/38 reads (58%) | catalogued as rs1168745368; called by muse, mutect2, varscan2
- U2AF1L4 | c.579-20C>T | Intron (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2, varscan2
- UBBP4 | n.820G>A | RNA (SNP) | VAF 162/433 reads (37%) | catalogued as rs1243531653; called by muse, varscan2
- UCHL5 | c.-223G>A | 5'UTR (SNP) | VAF 62/607 reads (10%) | catalogued as COSV104427389; called by muse, mutect2
- WDR20 | chr14:102212599 G>C | 3'Flank (SNP) | VAF 29/160 reads (18%) | called by muse, mutect2, varscan2
- ZBTB7B | c.-6G>C | 5'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, varscan2
- ZFP90 | c.257-45C>G | Intron (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- ZNF391 | c.-230G>A | 5'UTR (SNP) | VAF 26/128 reads (20%) | catalogued as rs918083554; called by muse, mutect2, varscan2
- ZNF720 | c.361+762C>T | Intron (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2, varscan2
